Surgical pathology report (de-identified scan), TCGA case TCGA-F7-A623, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Asterand, specimen TCGA-F7-A623-01A (Primary Tumor).

Gross Description:

Microscopic Description:

Diagnosis Details: Tumor location: Subglottis

Comments:

Formatted Path Reports: LARYNX TISSUE CHECKLIST

Specimen type: Laryngectomy

Tumor site: Larynx

Tumor size: 3 x 4 x 2.5 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Well differentiated

Tumor extent: Not specified

Lymph nodes: 2/6 positive for metastasis (Regional 2/6)

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Comments: Tumor location: Subglottis

ICD-O-3
Carcinoma, squamous cell NOS
8070/3
Site path Larynx, sub-glottis C32.2
C&F Larynx, NOS C32.9
JW 4/12/13

Dx at Synchronous Primary Noted		✓

Source: NCI Genomic Data Commons file 39834bd1-70b7-49c1-b87a-320952dc4760 (TCGA-F7-A623.DE5FC874-80AE-4DAA-BDB0-62F7B8DE156D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).